Somatic mutation profile of tumor specimen MBCProject_0315_T1_WES (aliquot MBCProject_0315_T1_WES_1) from CMI case MBCProject_0315, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0315_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7123e628-e706-4c24-b12d-1f7e19dd86eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0315_SALIVA (Saliva), aliquot MBCProject_0315_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f147a0a9-4dcf-4cf4-baa3-b80b95089ef8

The open-access MAF lists 43 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Intron 4, 3'UTR 2, Frame Shift Del 2, RNA 1, Nonsense Mutation 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AIP | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 342/1458 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653456; called by muse, mutect2, varscan2
- CDH1 | c.926del p.P309Lfs*47 | Frame Shift Del (DEL) | VAF 73/264 reads (28%) | catalogued as COSV55745635; called by mutect2, pindel, varscan2
- COL6A3 | c.2600A>G p.N867S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs751459281; called by muse, mutect2, varscan2
- DLGAP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747744035, COSV70103813; called by muse, mutect2, varscan2
- KMT2D | c.9349G>A p.E3117K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1316713931, COSV56417554; called by muse, mutect2, varscan2
- LIG3 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764983968; called by muse, mutect2, varscan2
- NAA15 | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV56718689; called by muse, mutect2
- NIBAN1 | c.716A>G p.Q239R | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as rs554209986; called by muse, mutect2, varscan2
- PCDHB11 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 99/437 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV61309775; called by muse, mutect2, varscan2
- PCDHB12 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 127/659 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1170138951, COSV53393512; called by muse, mutect2, varscan2
- TRIP13 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs754712257, COSV51319602; called by muse, varscan2
- ZNF831 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs200891052; called by muse, mutect2, varscan2
- ADAM30 | c.1756T>C p.C586R | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIP | c.992G>C p.*331Sext*? | Nonstop Mutation (SNP) | VAF 226/1012 reads (22%) | called by muse, varscan2
- AKT3 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ASS1 | c.144_147delinsAGGA p.K49G | Missense Mutation (ONP) | VAF 24/228 reads (11%) | called by pindel, varscan2*
- CTTN | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 98/810 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- FAP | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- GRAMD1A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- MLLT10 | c.509+2_509+4dup p.X170_splice | Splice Site (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- PCARE | c.2438C>G p.A813G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PIGR | c.1809G>T p.R603S | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPAG11A | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZFPM1 | c.1823_1838del p.D608Afs*185 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- AIP | c.936G>T p.R312= | Silent (SNP) | VAF 274/1218 reads (22%) | called by muse, varscan2
- C12orf42 | c.696G>T p.L232= | Silent (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- CCDC168 | c.14529A>G p.Q4843= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs182913889; called by muse, mutect2, varscan2
- CPA2 | c.963C>G p.T321= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- GLYATL3 | c.93G>A p.V31= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs928845850; called by muse, mutect2, varscan2
- GPR152 | c.225C>T p.L75= | Silent (SNP) | VAF 56/276 reads (20%) | called by muse, mutect2, varscan2
- PCDHA4 | c.2232G>A p.A744= | Silent (SNP) | VAF 73/251 reads (29%) | catalogued as rs1425791454; called by muse, mutect2, varscan2
- PTPN7 | c.153C>T p.D51= (on ENST00000495688; = p.D90= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as rs377638610, COSV58312042; called by muse, mutect2, varscan2
- SELENOO | c.1578C>T p.I526= | Silent (SNP) | VAF 93/372 reads (25%) | catalogued as rs34704774; called by muse, mutect2, varscan2
- SLC9A6 | c.1668G>A p.P556= | Silent (SNP) | VAF 47/308 reads (15%) | catalogued as rs1060504687, COSV100857883; ClinVar: likely benign; called by muse, mutect2, varscan2
- TOP2A | c.856T>C p.L286= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- AC104472.1 | n.326C>T | RNA (SNP) | VAF 8/36 reads (22%) | catalogued as rs899708885; called by muse, mutect2, varscan2
- ATP1A3 | c.510+10G>A | Intron (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
- CTAG2 | c.*109G>A | 3'UTR (SNP) | VAF 43/318 reads (14%) | called by muse, mutect2, varscan2
- RFC5 | c.66-1083C>T | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs1461403829; called by muse, mutect2
- SLC6A8 | c.1495+33G>T | Intron (SNP) | VAF 128/371 reads (35%) | called by muse, mutect2, varscan2
- SPAG11B | c.*67G>T | 3'UTR (SNP) | VAF 34/460 reads (7%) | catalogued as rs1563340351; called by muse, mutect2
- TRIM9 | c.1604-3932C>T | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
